Gene-level copy-number profile of tumor specimen TCGA-66-2800-01A from TCGA case TCGA-66-2800, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 70.7 years (25,810 days).
Specimen TCGA-66-2800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.eb78836a-1802-4d6c-a80f-24154b5005a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2800-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f911bd1-4273-4376-8e06-a67afd5c83bf

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 1,654; copy number 2: 19,877; copy number 3: 10,516; copy number 4: 20,540; copy number 5: 3,875; copy number 6: 1,794; copy number 7: 562; copy number 10: 123; copy number 12: 775; copy number 14: 5; copy number 21: 45; copy number 23: 9; copy number 24: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2800-01A-01D-1195-01): tumor purity 0.52, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–25,089,151, 31 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 963 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,095,905–198,222,513, 708 genes, copy number 12 (broad region; genes not listed).
- chr6:44,809,317–45,664,349, 9 genes, copy number 23 (within-gene range 3–23): SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr6:46,096,004–47,627,263, 25 genes, copy number 21 (within-gene range 4–21): AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:124,644,434–125,445,193, 6 genes, copy number 24: RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1.
- chr6:154,832,697–155,257,723, 1 gene, copy number 21 (within-gene range 3–21): TIAM2.
- chr6:155,004,835–157,210,779, 19 genes, copy number 21 (within-gene range 3–21): AL136228.1, AL596202.1, TFB1M, CLDN20, AL031773.1, NOX3, RNU7-152P, AL589693.1, MIR1202, AL512658.2, SNORD28B, AL512658.1, H3P28, AL355297.2, ARID1B, AL355297.3, MIR4466, AL355297.1, AL162578.1.
- chr8:41,577,187–43,674,591, 67 genes, copy number 12 (broad region; genes not listed).
- chr9:25,579,657–26,118,408, 5 genes, copy number 14: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr14:18,333,726–20,477,089, 123 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
